Surgical pathology report (de-identified scan), TCGA case TCGA-33-4583, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4583-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1. BRONCHIAL MARGIN (EXCISION): NEGATIVE FOR TUMOR.

2. LUNG, LEFT LOWER LOBE (LOBECTOMY): MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (3.0 CM). BRONCHIAL AND VASCULAR MARGINS ARE ACTIVE FOR TUMOR. TWO (2) OF TWO (2) HILAR LYMPH NODES AND TWO (2) OF TWO (2) INTRAPULMONARY LYMPH NODES ARE NEGATIVE FOR TUMOR. AN EXTENSIVE LIPOID AND FOREIGN BODY PNEUMONIA IS PRESENT. THIS FEATURE SUGGESTS ASPIRATION. THE PATHOLOGICAL STAGE IS pT1 N0 MX.

3. LYMPH NODES, UPPER LOBE (EXCISION): ONE (1) LYMPH NODES, NEGATIVE FOR TUMOR.

4. LYMPH NODE, LEVEL 5 (EXCISION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

[REDACTED]

[REDACTED]

[REDACTED] TCGA-33-4583

Source: NCI Genomic Data Commons file e636c8ce-4ef3-4aa9-9cdd-f57a874108f3 (TCGA-33-4583.535235C0-4540-4638-B799-B7DFD082F5B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).